Gene-level copy-number profile of tumor specimen TCGA-BA-6873-01A from TCGA case TCGA-BA-6873, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 28.8 years (10,512 days).
Specimen TCGA-BA-6873-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.73e7511c-092c-402a-83db-af7f5f894a77.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BA-6873-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fe5aaa24-afca-4ae3-aade-b041f5af2ed5

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 4,818; copy number 3: 23,544; copy number 4: 23,361; copy number 5: 2,723; copy number 6: 4,041; copy number 7: 564; copy number 8: 221; copy number 9: 129; copy number 10: 123; copy number 11: 165; copy number 12: 33; copy number 14: 92.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BA-6873-01A-11D-1869-01): tumor purity 0.41, ploidy 3.66, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,327 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:149,129,638–154,970,223, 115 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr3:164,001,606–165,846,519, 9 genes, copy number 8–14 (within-gene range 6–14): AC084017.1, MIR1263, LINC01323, LINC01324, SI, Y_RNA, LINC02023, SLITRK3, LINC01322.
- chr3:166,569,693–179,267,002, 178 genes, copy number 7–11 (broad region; genes not listed).
- chr3:182,049,058–183,463,201, 30 genes, copy number 7: AC012081.2, AC012081.1, AC109131.1, AC084211.1, LINC01994, EIF4EP3, LINC01995, AC021055.1, RPL7L1P8, LINC02031, AC083801.1, AC083801.2, AC069431.1, ATP11B, AC069431.2, AC092953.2, DCUN1D1, AC092953.1, MCCC1, MCCC1-AS1, LAMP3, MCF2L2, B3GNT5, RNA5SP151, LINC00888, SNORA63D, AC092960.2, SNORA63E, AC092960.1, AC092960.3.
- chr5:58,198–2,262,023, 79 genes, copy number 8 (broad region; genes not listed).
- chr11:58,291,826–58,761,053, 23 genes, copy number 7: OR10Q2P, OR5BC1P, OR5B19P, OR5B10P, AP000435.1, OR5B17, OR5B1P, OR5B15P, OR5B3, OR5B2, OR5B12, AP003557.2, AP003557.1, OR5B21, LPXN, ZFP91, ZFP91-CNTF, AP001350.1, CNTF, AP001350.2, GLYAT, AP000445.1, AP000445.2.
- chr11:65,568,482–67,317,431, 108 genes, copy number 9 (within-gene range 3–9) (broad region; genes not listed).
- chr12:1,929,202–7,158,945, 182 genes, copy number 7–12 (broad region; genes not listed).
- chr12:12,715,058–12,841,079, 8 genes, copy number 14: CDKN1B, AC008115.3, AC008115.1, APOLD1, MIR613, STX8P1, DDX47, AC007215.1.
- chr14:78,170,373–79,868,291, 1 gene, copy number 7 (within-gene range 6–7): NRXN3.
- chr14:78,695,321–88,098,025, 81 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr15:98,648,539–98,964,530, 1 gene, copy number 11 (within-gene range 4–11): IGF1R.
- chr15:98,784,426–100,544,995, 37 genes, copy number 11 (within-gene range 5–11): MIR4714, AC055807.1, AC069029.1, AC036108.1, PGPEP1L, LUNAR1, SYNM, AC036108.2, TTC23, AC036108.3, AC022819.1, LRRC28, HSP90B2P, HNRNPA1P62, AC037479.1, LINC02244, AC015660.2, AC015660.3, AC015660.1, AC015660.5, AC015660.4, RPL7P5, MEF2A, Y_RNA, LYSMD4, DNM1P46, AC090825.2, RN7SL484P, AC090825.1, AC084855.1, ADAMTS17, AC084855.2, RNA5SP402, AC022710.1, SPATA41, CERS3-AS1, CERS3.
- chr19:12,965,159–13,778,773, 20 genes, copy number 9: DAND5, NFIX, AC138474.1, AC007787.1, AC007787.2, LYL1, TRMT1, NACC1, AC005546.1, AC011446.1, STX10, IER2, AC011446.3, AC011446.2, RPL12P42, CACNA1A, CCDC130, MRI1, AC008686.1, C19orf53.
- chr19:13,796,574–13,796,933, 1 gene, copy number 9: AC020916.2.
- chr22:20,424,584–29,312,785, 444 genes, copy number 7–14 (broad region; genes not listed).
- chr22:50,669,804–50,801,309, 10 genes, copy number 8: Y_RNA, AC000050.2, SHANK3, RNU6-409P, AC000036.1, ACR, AC002056.2, AC002056.1, RPL23AP82, RABL2B.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
